Somatic mutation profile of tumor specimen TCGA-EJ-A7NG-01A (aliquot TCGA-EJ-A7NG-01A-31D-A33T-08) from TCGA case TCGA-EJ-A7NG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.2 years (23,458 days).
Specimen TCGA-EJ-A7NG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b90ba3-a545-40fa-9bcc-751dde4f0ab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NG-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NG-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52fa747b-7991-4e91-b789-010a8b62f98e

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ULK4 | c.2666C>G p.T889R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100092243, COSV57208792; called by mutect2, varscan2
- ZNF492 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | catalogued as COSV71761705; called by muse, mutect2
- ADD2 | c.1950C>T p.N650= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as rs1553365524, COSV52458845; called by muse, mutect2
